Somatic mutation profile of tumor specimen TARGET-10-PASFKA-09A (aliquot TARGET-10-PASFKA-09A-01D) from TARGET case TARGET-10-PASFKA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.8 years (4,666 days).
Specimen TARGET-10-PASFKA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bf622fe-4858-4178-baf8-c4af52fd71df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASFKA-10A (Blood Derived Normal), aliquot TARGET-10-PASFKA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da907d1d-6606-4004-aea9-7ffcc7616dbb

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Splice Site 1, 5'UTR 1, RNA 1, Intron 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 134/150 reads (89%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC109583.1 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368367787, COSV58406443; called by muse, mutect2, varscan2
- ACKR2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV56177062; called by muse, mutect2, varscan2
- DNMT1 | c.4277G>T p.R1426L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV61580671, COSV61582775; called by muse, mutect2
- MOCOS | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767918050, COSV54346292; called by muse, mutect2, varscan2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2, varscan2
- PHF11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV57904535; called by muse, mutect2, varscan2
- RPL22 | c.12+1G>C p.X4_splice | Splice Site (SNP) | VAF 24/52 reads (46%) | catalogued as COSV52377262, COSV52379110; called by muse, varscan2
- SEC24A | c.1174A>T p.S392C | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as COSV59749384; called by muse, mutect2, varscan2
- TCF7L1 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV56400253, COSV56402482; called by muse, mutect2, varscan2
- BPTF | c.1250T>C p.V417A | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGHV3-33 | chr14:106359791 TCTC>GAA | Missense Mutation (DEL) | VAF 43/86 reads (50%) | called by pindel, varscan2*
- KANK2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- USP7 | c.912delinsTCTTCGAGTGCTCGA p.D305Lfs*12 | Frame Shift Ins (INS) | VAF 15/30 reads (50%) | called by pindel, varscan2*
- BLACE | n.1536_1537insTTTT | RNA (INS) | VAF 45/165 reads (27%) | called by mutect2, pindel, varscan2
- P2RX4 | c.135-18G>C | Intron (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- VAMP4 | c.-9G>A | 5'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
